Surgical pathology report (de-identified scan), TCGA case TCGA-LN-A9FO, project TCGA-ESCA (Esophageal Carcinoma), tissue source site ILSBIO, specimen TCGA-LN-A9FO-01A (Primary Tumor).

[page 1 of 4]
Clinical Case Report **(For Collection of Cancerous Tissue)**

ICD-0-3

Carcinoma, squamous cell NOS
Site esophagus, distal third
C15.9
8070/3
C155
4/17/14

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
		☐ Single ☒ Married ☐ Divorced ☐ Widow	Wt 170	
Gender	Weight		Blood Pressure	Heart Rate
☒ Male ☐ Female				

HISTORY OF PRESENT ILLNESS	
Chief Complaints:	Dysphagia,
Symptoms:	Weight loss, chest pain.
Clinical Findings:	Noct finding Spectral Symptom
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden	

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
Wt				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 4]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status
WJZ			

OB/GYN HISTORY WJZ		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation: _____		Environmental Hazards: None		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO	Cigarette	01	> 10 (yrs)	WJZ (yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO	Beer	Some time	> 5 (yrs)	WJZ (yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis
WJZ know		

LAB DATA					
Test	Result	Date	Test	Result	Date
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____	WJZ dm
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____	9
Hep C	☐ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____	7
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____	7
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers: _____					

[page 3 of 4]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	Not	
X-Ray	not	
CT	not	
Endoscopy	Tumor in esophagus	
MRI	not	
Biopsy	Squamous cell carcinoma	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Esophagus cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
not	not	
Clinical Staging		Date of Diagnosis
T ₂ N ₀ M ₀ Stage: 2A		

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Remove Esophagus and part of stomach:			
Primary Tumor			
Organ	Detailed Location		Size
Esophagus	Esophagus		3 x 1 x 2 cm
Extension of Tumor			
> 1 cm			
Lymph Nodes			
Description	Location of Lymph Nodes		# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location		Size
Surgical Staging			
T ₂ N ₀ M ₀ Stage: 2A			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 4]
Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse				✓	Streaming				✓		
Mosaic			✓		Storiform				✓		
Necrosis				✓	Fibrosis				✓		
Lymphocytic Infiltration				✓	Palisading				✓		
Vascular Invasion				✓	Cystic Degeneration				✓		
Clusterized				✓	Bleeding				✓		
Alveolar Formation				✓	Myxoid Change				✓		
Indian File				✓	Psammoma/Calcification				✓		

Cellular Differentiation															
Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-	Lymphomatous		+	-
Squamoid Cell		✓		Glandular cell			✓	Round Cell			✓	Large Cell			✓
Spindle Cell			✓	Cell Stratification			✓	Fibroblast			✓	Small Cell			✓
Keratin		✓		Secretion			✓	Osteoblast			✓	RS Cell/RS Like			✓
Desmosome		✓		Intracyt. Vacuole			✓	Lipoblast			✓	Inflam. Cell			✓
Pearl			✓	Gland formation			✓	Myoblast			✓	Plasma Cell			✓

Cellular Differentiation:				Well ✓	Moderate	Poor
----------------------------------	--	--	--	--------	----------	------

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis		✓		
Hyperchromatism		✓		
Nucleolar Prominent		✓		
Multinucleated Giant Cell	✓			
Mitotic Activity		✓		

Nuclear Grade:				
		✓		

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive	Not done	
PR	☐ Negative ☐ Positive	✓	
Her-2/neu	☐ Negative ☐ Positive	✓	
B-Cell Marker	☐ Negative ☐ Positive	✓	
T-Cell Marker	☐ Negative ☐ Positive	✓	
Other:	☐ Negative ☐ Positive	✓	
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Squamous Cell Carcinoma well differentiated
involved to muscle layer **Grade:** 1

Comments:

Principal Investigator

Pathologist

Date

Source: NCI Genomic Data Commons file c280dffe-bba9-4ed2-b84e-b8e28f814198 (TCGA-LN-A9FO.5FBD6D37-4C58-4E7F-8729-360B2D024ED2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).